CPTAC case C3N-00247 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94fd2f4b-4624-4c77-b02e-8943cffcabd1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 77.6 years (28,330 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,580 days (4.3 years); Progression or recurrence: no; Days to last follow up: 1,580 days (4.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm (a second GDC size field records 4.2 cm); Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 17; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 805 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,070 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,580 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,580 days (4.3 years); Disease response: Complete Response.
- Follow-up contact recording only the day: day 385.

Other clinical attributes
- Weight: 74.84 kg; Height: 165.1 cm; BMI: 27.45.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2.5; Cigarettes per day: 10; Tobacco smoking onset year: 1969; Tobacco smoking quit year: 1974; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 5.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00247-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 125.7 mg.
- Sample C3N-00247-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 57 days; Initial weight: 150.5 mg; Time between excision and freezing: 31 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00247-22: Section location: Right Lower Lobe; Percent tumor nuclei: 65; Percent necrosis: 5.
- Sample C3N-00247-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 64.1 mg.
- Sample C3N-00247-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 117.4 mg.
- Sample C3N-00247-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 84.7 mg.
- Sample C3N-00247-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 57 days; Method of sample procurement: Blood Draw.
- Sample C3N-00247-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
